MMRF case MMRF_1613 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e9b31ae7-734d-4915-a186-db19aaa7a55e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.3 years (27,126 days); ISS stage: II; Days to last known disease status: 1,251 days (3.4 years); Days to last follow up: 1,251 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 115 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 393 days (1.1 years); Days to treatment end: 796 days (2.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 466 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 489 days (1.3 years); Days to treatment end: 1,279 days (3.5 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 796 days (2.2 years); Days to treatment end: 1,251 days (3.4 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,258 days (3.4 years); Days to treatment end: 1,279 days (3.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 0): M Protein 9.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 100 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 4.84 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.15 mmol/L; Albumin 23 g/L; Total Protein 16.4 g/dL; Glucose 4.9 mmol/L.
- Day 82 (ECOG 1): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 4.77 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6.53 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 173 (ECOG 1): M Protein 6.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 6.94 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.02 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.44 mmol/L.
- Day 258 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 6.11 mmol/L.
- Day 335 (ECOG 1): Hemoglobin 7.69 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.58 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.12 mmol/L.
- Day 425 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.3 µg/mL; Hemoglobin 8.12 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 5.94 mmol/L.
- Day 517 (ECOG 0): M Protein 1.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.7 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.85 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 7.1 mmol/L.
- Day 601: M Protein 1.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Beta 2 Microglobulin 3 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 8.1 g/dL; Glucose 6.27 mmol/L.
- Day 692: M Protein 3.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 37.5 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 8.8 g/dL; Glucose 5.23 mmol/L.
- Day 796: M Protein 5.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 58.1 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 8.4 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 0.97 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 10.6 g/dL; Glucose 8.42 mmol/L.
- Day 874: M Protein 3.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 37.9 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.71 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 9.4 g/dL; Glucose 8.09 mmol/L.
- Day 951: M Protein 3.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 43.7 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.48 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2 mmol/L; Albumin 31 g/L; Total Protein 9.2 g/dL; Glucose 9.41 mmol/L.
- Day 1,049: M Protein 3.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 41.4 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 5.77 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 8.8 g/dL; Glucose 7.59 mmol/L.
- Day 1,132: M Protein 5.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 58.7 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 5.33 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 28 g/L; Total Protein 10.5 g/dL; Glucose 7.1 mmol/L.
- Day 1,251: M Protein 6.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 26.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 81.6 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 4.96 mmol/L; Leukocytes 10.7 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.05 mmol/L; Albumin 27 g/L; Total Protein 12.6 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -23: Weight: 90 kg; Height: 192 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1613_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_1613_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
